Somatic mutation profile of tumor specimen TCGA-HT-7854-01A (aliquot TCGA-HT-7854-01A-11D-2253-08) from TCGA case TCGA-HT-7854, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Astrocytoma, NOS; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 62.3 years (22,738 days).
Specimen TCGA-HT-7854-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0432d6e4-4e63-4f63-b0bb-dfd893ed0ea8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HT-7854-10A (Blood Derived Normal), aliquot TCGA-HT-7854-10A-01D-2253-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7de1534d-f4a3-443b-add9-d83a5080bebb

The open-access MAF lists 23 somatic variants for this specimen: 17 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 13, Silent 6, Frame Shift Ins 2, Splice Region 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTPN11 | c.922A>G p.N308D | Missense Mutation (SNP) | VAF 14/63 reads (22%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen benign (0.134); catalogued as rs28933386, CM013422, COSV61006575; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCA13 | c.12904C>T p.Q4302* | Nonsense Mutation (SNP) | VAF 30/154 reads (19%) | catalogued as rs752248896, COSV68946594; called by muse, mutect2, varscan2
- ABCA7 | c.4483C>T p.L1495F | Missense Mutation (SNP) | VAF 30/119 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54029282; called by muse, mutect2, varscan2
- ADGRV1 | c.16368G>A p.K5456= | Splice Region (SNP) | VAF 11/26 reads (42%) | catalogued as COSV67984989; called by muse, mutect2, varscan2
- AMPD2 | c.370C>G p.L124V | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.069); catalogued as COSV56647839; called by muse, mutect2, varscan2
- ATP10B | c.1340G>A p.R447H | Missense Mutation (SNP) | VAF 27/77 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs376023056; called by muse, mutect2, varscan2
- CFAP61 | c.3190G>A p.E1064K | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.031); catalogued as COSV55628956; called by muse, mutect2, varscan2
- GRID2 | c.2144G>A p.S715N | Missense Mutation (SNP) | VAF 22/116 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs778573966, COSV56204439; called by muse, mutect2, varscan2
- KIR2DL1 | c.1030G>A p.V344I | Missense Mutation (SNP) | VAF 98/311 reads (32%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.995); catalogued as rs1234518600; called by muse, mutect2, varscan2
- KRT20 | c.254T>A p.L85Q | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51424874; called by muse, mutect2, varscan2
- MAPK4 | c.340C>T p.R114C | Missense Mutation (SNP) | VAF 11/95 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.025); catalogued as rs186595195, COSV68541012; called by muse, mutect2, varscan2
- PDE4D | c.652G>A p.G218R (on ENST00000340635 / NM_001104631.2; = p.G82R on NM_006203.4) | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.997); catalogued as rs763492345, COSV58955720; called by muse, mutect2, varscan2
- RNF208 | c.737C>T p.A246V | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.012); catalogued as rs769653356, COSV61287677; called by muse, mutect2
- TAF1 | c.3752G>T p.G1251V (on ENST00000373790 / NM_138923.4; = p.G1272V on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52113125; called by muse, mutect2, varscan2
- TMTC2 | c.2024A>G p.D675G | Missense Mutation (SNP) | VAF 40/120 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); catalogued as COSV58268400; called by muse, mutect2, varscan2
- DNAI4 | c.192_193insT p.K65* | Frame Shift Ins (INS) | VAF 13/31 reads (42%) | called by mutect2, pindel, varscan2
- NCOR2 | c.6748dup p.E2250Gfs*49 | Frame Shift Ins (INS) | VAF 26/104 reads (25%) | called by mutect2, pindel, varscan2
- ACOT8 | c.720G>C p.L240= | Silent (SNP) | VAF 18/79 reads (23%) | catalogued as COSV54169430; called by muse, mutect2, varscan2
- ATN1 | c.3318C>T p.H1106= | Silent (SNP) | VAF 18/73 reads (25%) | catalogued as rs370442635, COSV57546819; called by muse, mutect2, varscan2
- CD300A | c.553C>T p.L185= | Silent (SNP) | VAF 21/113 reads (19%) | catalogued as COSV60410072; called by muse, mutect2, varscan2
- FCHO1 | c.2382G>A p.V794= | Silent (SNP) | VAF 22/169 reads (13%) | catalogued as rs1440973695, COSV53182535, COSV53185828; called by muse, mutect2, varscan2
- IL16 | c.925C>T p.L309= | Silent (SNP) | VAF 19/46 reads (41%) | catalogued as COSV57263496, COSV57266619; called by muse, mutect2, varscan2
- NTF3 | c.417C>T p.Y139= | Silent (SNP) | VAF 38/159 reads (24%) | catalogued as rs1416749123, COSV58417608; called by muse, mutect2, varscan2
